TCGA case TCGA-CZ-5457 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Harvard. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f00b7956-73a9-4e4b-85d2-60b3ba13f4a4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (3)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 62.3 years (22,763 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 62.8 years (22,937 days); Days to diagnosis: 174 days; Prior treatment: Yes.
   Recorded as not given: Surgery, NOS to Distant Site.
3. Metastasis of diagnosis 1 (Clear cell adenocarcinoma, NOS). Age at diagnosis: 62.8 years (22,937 days); Days to diagnosis: 174 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 174 days; Treatment anatomic sites: Distant Site.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Locoregional Site.

Follow-up (5 entries)
- Day 174 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 174 days.
- Days to follow up: 1,547 days (4.2 years); Disease response: With Tumor.
- Days to follow up: 1,683 days (4.6 years); Disease response: With Tumor.
- Days to follow up: 2,754 days (7.5 years); Disease response: With Tumor.
- Karnofsky performance status: 100; Timepoint: Preoperative.

Molecular and laboratory tests
- Platelets: Normal.
- Leukocytes: Elevated.
- Calcium: Low.
- Hemoglobin: Low.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CZ-5457-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 0.7; Shortest dimension: 0.2.
  Slide TCGA-CZ-5457-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-CZ-5457-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-CZ-5457-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CZ-5457-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 1.3; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Serum calcium level: Low; Hemoglobin level: Low; Lymph nodes examined: No.
- Follow-up form 1: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: Yes.
- Follow-up form 3: Lost to follow-up: No; Treatment outcome at TCGA followup: Progressive Disease; Tumor status: With tumor; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,754 days; disease-specific survival: no event (censored), 2,754 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 174 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CZ-5457-01A-01D-1499-01): tumor purity 0.46, ploidy 2.81, whole-genome doublings 1.
